CCDI case PBCLTA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8fd0370c-9268-4e2d-8ac7-4c97ce5977eb

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.6 years (2,051 days).

Biospecimens (3 samples)
- Sample 0DWD1H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWD1Y: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWD2E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
